Somatic mutation profile of cancer-model specimen HCM-CSHL-0376-D37-85P (3D Organoid; aliquot HCM-CSHL-0376-D37-85P-01D-A78T-36), derived from the premalignant tumor of HCMI case HCM-CSHL-0376-D37, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 75.4 years (27,551 days).
Specimen HCM-CSHL-0376-D37-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4ef59ca-7f54-4a84-8c7b-92760d8388e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0376-D37-10A (Blood Derived Normal), aliquot HCM-CSHL-0376-D37-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45729700-e285-4e03-8183-c6671e0ae009

The open-access MAF lists 159 somatic variants for this specimen: 111 protein-altering or splice-affecting, 32 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 32, Nonsense Mutation 9, Intron 8, RNA 4, Frame Shift Ins 4, Splice Site 3, 5'UTR 2, Frame Shift Del 2, 3'UTR 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 194/419 reads (46%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD17A | c.431C>T p.S144F (on ENST00000292577 / NM_001130111.2; = p.S195F on NM_031213.4) | Missense Mutation (SNP) | VAF 254/566 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51749734; called by muse, mutect2, varscan2
- ADARB2 | c.1586C>A p.T529K | Missense Mutation (SNP) | VAF 179/365 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101187605; called by muse, mutect2, varscan2
- AMY2A | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 191/470 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs145483775; called by muse, mutect2, varscan2
- APC | c.3673G>A p.A1225T | Missense Mutation (SNP) | VAF 103/237 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs776079894; called by muse, mutect2, varscan2
- APC | c.4334del p.T1445Kfs*28 | Frame Shift Del (DEL) | VAF 67/169 reads (40%) | catalogued as COSV57341535, COSV57358206; called by mutect2, pindel, varscan2
- ATCAY | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 115/288 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1323208400, COSV56657458; called by muse, mutect2, varscan2
- AXL | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1009680105, COSV56574008; called by muse, mutect2, varscan2
- BBS7 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 134/313 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs751170388, COSV52659184; called by muse, mutect2, varscan2
- CALCR | c.130G>T p.G44* | Nonsense Mutation (SNP) | VAF 95/232 reads (41%) | catalogued as COSV64007089; called by muse, mutect2, varscan2
- CDH11 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 162/303 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556647809, COSV51756679, COSV51758059; called by muse, mutect2, varscan2
- CFH | c.3634C>G p.H1212D | Missense Mutation (SNP) | VAF 256/589 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.048); catalogued as COSV66410045, COSV66414787; called by muse, mutect2, varscan2
- CHERP | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs527535661; called by muse, mutect2, varscan2
- CLDN18 | c.33C>A p.F11L | Missense Mutation (SNP) | VAF 137/294 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as rs1330042724, COSV59301692; called by muse, mutect2, varscan2
- CRYGA | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 206/424 reads (49%) | catalogued as rs1430852017; called by muse, mutect2, varscan2
- CSMD1 | c.8057C>T p.P2686L (on ENST00000520002; = p.P2685L on NM_033225.6) | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.828); catalogued as rs529988284; called by muse, mutect2, varscan2
- CYP4F22 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 321/669 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs746979996, COSV54107214; called by muse, mutect2, varscan2
- DOCK4 | c.2479C>T p.R827* | Nonsense Mutation (SNP) | VAF 59/121 reads (49%) | catalogued as rs1283720924, COSV101447941; called by muse, mutect2, varscan2
- ECSIT | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 78/151 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs758391824; called by muse, mutect2, varscan2
- EXOC3L1 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 81/207 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139069832; called by muse, mutect2, varscan2
- FNDC1 | c.4484C>T p.T1495M | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs564106720, COSV51947396; called by muse, mutect2, varscan2
- FSD1 | c.773C>G p.S258C | Missense Mutation (SNP) | VAF 129/242 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV55695361; called by muse, mutect2, varscan2
- GAB4 | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs762931159, COSV101271901; called by muse, mutect2, varscan2
- GAP43 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs753056251; called by muse, mutect2, varscan2
- GIMAP1 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.005); catalogued as rs752300708, COSV56188181; called by muse, mutect2, varscan2
- GP1BA | c.1480dup p.T494Nfs*4 | Frame Shift Ins (INS) | VAF 206/508 reads (41%) | catalogued as rs759573909; called by mutect2, varscan2
- GPR132 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 76/373 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs796551979, COSV61678212; called by muse, mutect2, varscan2
- GPR142 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 225/450 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs766708510, COSV59519286; called by muse, mutect2, varscan2
- HAS1 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 76/154 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as rs767100794; called by muse, mutect2, varscan2
- HOPX | c.193C>T p.P65S (on ENST00000317745; = p.P83S on NM_032495.6) | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs773904855; called by muse, mutect2, varscan2
- IGF1R | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 250/492 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.695); catalogued as rs1567180721; called by muse, mutect2, varscan2
- KCNH1 | c.1558C>T p.R520W (on ENST00000271751 / NM_172362.3; = p.R493W on NM_002238.4) | Missense Mutation (SNP) | VAF 170/390 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55076714; called by muse, mutect2, varscan2
- KCNS3 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 87/181 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs371345847, COSV100411601; called by muse, mutect2, varscan2
- LCOR | c.2989G>A p.E997K | Missense Mutation (SNP) | VAF 126/243 reads (52%) | SIFT tolerated (0.56); PolyPhen benign (0.021); catalogued as rs778351999, COSV53714581; called by muse, mutect2, varscan2
- LCT | c.4685C>A p.T1562N | Missense Mutation (SNP) | VAF 151/280 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.371); catalogued as COSV51553545; called by muse, mutect2, varscan2
- MAGEL2 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.993); catalogued as rs1459919141; called by muse, mutect2, varscan2
- MEN1 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 171/351 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1254459338; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- N4BP2 | c.2981C>T p.T994M | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.395); catalogued as rs199590556; called by muse, mutect2, varscan2
- NFASC | c.3226C>T p.R1076W | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs370375266; called by muse, mutect2, varscan2
- NKTR | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs528288636; called by muse, mutect2, varscan2
- NYAP2 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 155/380 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.997); catalogued as rs568027472, COSV99796316; called by muse, mutect2, varscan2
- OR5B12 | c.597dup p.V200Cfs*6 | Frame Shift Ins (INS) | VAF 64/148 reads (43%) | catalogued as rs747074822; called by mutect2, varscan2
- PCDH17 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 221/426 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1225886813, COSV64977246; called by muse, mutect2, varscan2
- PCDHB8 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 478/1058 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50769362; called by muse, mutect2, varscan2
- PCDHGA6 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 125/269 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs774211225, COSV53938866, COSV54020485; called by muse, mutect2, varscan2
- PGAP6 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs141378431; called by muse, mutect2, varscan2
- PHTF2 | c.584C>T p.P195L (on ENST00000248550 / NM_001366089.1; = p.P157L on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs200528794; called by muse, mutect2, varscan2
- PIEZO2 | c.6181G>A p.G2061S | Missense Mutation (SNP) | VAF 254/485 reads (52%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs754406783, COSV53291567; called by muse, mutect2, varscan2
- PRR16 | c.320C>A p.P107Q (on ENST00000407149 / NM_001300783.2; = p.P84Q on NM_016644.2) | Missense Mutation (SNP) | VAF 105/225 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV65398417; called by mutect2, varscan2
- PSD | c.1903C>T p.R635* | Nonsense Mutation (SNP) | VAF 210/474 reads (44%) | catalogued as COSV50042517; called by muse, mutect2, varscan2
- RGPD3 | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 58/431 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58742597; called by muse, mutect2, varscan2
- RIMBP2 | c.2671G>A p.A891T | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.083); catalogued as rs755615114, COSV55468877; called by muse, mutect2, varscan2
- SLC25A5 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 99/107 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58627645; called by muse, mutect2, varscan2
- SLC44A5 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 59/129 reads (46%) | catalogued as rs1339932913, COSV63764215; called by muse, mutect2, varscan2
- SOAT1 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 121/282 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs747795183; called by muse, mutect2, varscan2
- SOX7 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 83/166 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58730803; called by muse, mutect2, varscan2
- TCF15 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 116/250 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as rs952836687; called by muse, mutect2, varscan2
- THSD4 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 38/373 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs1444983326; called by muse, mutect2, varscan2
- TNKS | c.3328G>C p.D1110H | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100127998; called by muse, mutect2, varscan2
- TNRC6B | c.1370G>A p.W457* | Nonsense Mutation (SNP) | VAF 200/423 reads (47%) | catalogued as COSV100109740; called by muse, mutect2, varscan2
- TRIM9 | c.1948C>G p.L650V | Missense Mutation (SNP) | VAF 96/205 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1457643123; called by muse, mutect2, varscan2
- UNC45A | c.2111G>A p.G704E | Missense Mutation (SNP) | VAF 134/286 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1186118573; called by muse, mutect2, varscan2
- UNC79 | c.5381C>T p.A1794V (on ENST00000393151 / NM_001346218.2; = p.A1617V on NM_020818.5) | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV56371773; called by muse, mutect2
- ZBED9 | c.3524G>A p.R1175Q | Missense Mutation (SNP) | VAF 85/205 reads (41%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs776339464; called by muse, mutect2, varscan2
- ANKEF1 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- AQP10 | c.703T>A p.F235I | Missense Mutation (SNP) | VAF 124/260 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARR3 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 55/55 reads (100%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- ASB13 | c.766G>C p.V256L | Missense Mutation (SNP) | VAF 125/291 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ATE1 | c.40T>G p.Y14D | Missense Mutation (SNP) | VAF 111/255 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- BCOR | c.619dup p.L207Pfs*6 | Frame Shift Ins (INS) | VAF 184/254 reads (72%) | called by mutect2, pindel, varscan2
- CACNA1F | c.2893G>C p.V965L | Missense Mutation (SNP) | VAF 150/150 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CDKL5 | c.283-1G>A p.X95_splice | Splice Site (SNP) | VAF 116/116 reads (100%) | called by muse, mutect2, varscan2
- CFHR4 | c.890C>G p.S297C (on ENST00000367416 / NM_001201551.2; = p.S298C on NM_001201550.3) | Missense Mutation (SNP) | VAF 85/243 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- CLINT1 | c.1012+1G>T p.X338_splice | Splice Site (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- CLINT1 | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CTNNB1 | c.1805T>G p.L602R | Missense Mutation (SNP) | VAF 187/416 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH17 | c.10552G>A p.E3518K | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FREM3 | c.5308C>A p.L1770I | Missense Mutation (SNP) | VAF 164/287 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GTSE1 | c.1346T>C p.I449T | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KDM7A | c.1540C>G p.L514V | Missense Mutation (SNP) | VAF 164/398 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MKI67 | c.4292T>A p.I1431N | Missense Mutation (SNP) | VAF 290/622 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MUC16 | c.24338C>A p.T8113K | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MYH1 | c.937del p.Y313Mfs*20 | Frame Shift Del (DEL) | VAF 157/400 reads (39%) | called by mutect2, pindel, varscan2
- NETO1 | c.1391A>G p.K464R | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NIN | c.4731A>C p.K1577N (on ENST00000382041 / NM_182946.1; = p.K864N on NM_016350.4) | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRIP1 | c.3132G>T p.W1044C | Missense Mutation (SNP) | VAF 120/218 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NUP153 | c.1274T>G p.F425C | Missense Mutation (SNP) | VAF 83/164 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NUP98 | c.799G>T p.G267* | Nonsense Mutation (SNP) | VAF 50/110 reads (45%) | called by muse, mutect2, varscan2
- OR4D5 | c.568A>T p.T190S | Missense Mutation (SNP) | VAF 189/360 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- OR51Q1 | c.719T>A p.L240H | Missense Mutation (SNP) | VAF 96/163 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- OR51Q1 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 126/244 reads (52%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- P2RX5 | c.360+1G>A p.X120_splice | Splice Site (SNP) | VAF 61/245 reads (25%) | called by muse, mutect2, varscan2
- PLEKHG2 | c.139dup p.R47Pfs*15 | Frame Shift Ins (INS) | VAF 55/133 reads (41%) | called by mutect2, pindel, varscan2
- PRKCE | c.1762G>A p.V588M | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRR16 | c.319C>A p.P107T (on ENST00000407149 / NM_001300783.2; = p.P84T on NM_016644.2) | Missense Mutation (SNP) | VAF 106/228 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.442); called by mutect2, varscan2
- PRR16 | c.394G>C p.V132L (on ENST00000407149 / NM_001300783.2; = p.V109L on NM_016644.2) | Missense Mutation (SNP) | VAF 87/173 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RYR3 | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 99/236 reads (42%) | called by muse, mutect2, varscan2
- SEMA6C | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 187/463 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SH3BP2 | c.1220A>G p.K407R | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- SPTLC1 | c.126G>T p.K42N | Missense Mutation (SNP) | VAF 129/262 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- STRADA | c.647G>A p.S216N (on ENST00000336174 / NM_001363786.1; = p.S179N on NM_153335.6) | Missense Mutation (SNP) | VAF 157/323 reads (49%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- TMEM208 | c.44_64del p.I15_E21del | In Frame Del (DEL) | VAF 18/104 reads (17%) | called by mutect2, pindel
- TTC21B | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 116/276 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- TTN | c.70250T>G p.F23417C (on ENST00000591111; = p.F15993C on NM_003319.4) | Missense Mutation (SNP) | VAF 82/161 reads (51%) | PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- UBTFL1 | c.814C>G p.Q272E | Missense Mutation (SNP) | VAF 126/372 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); called by mutect2, varscan2
- UBXN7 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF592 | c.2288C>T p.A763V | Missense Mutation (SNP) | VAF 235/538 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ZNF679 | c.499A>G p.K167E | Missense Mutation (SNP) | VAF 143/308 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF777 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 345/673 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ZNF804B | c.3869C>T p.A1290V | Missense Mutation (SNP) | VAF 153/304 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ZNF880 | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.233); called by muse, varscan2
- AGBL5 | c.882C>T p.P294= | Silent (SNP) | VAF 63/149 reads (42%) | catalogued as rs375903966; called by muse, mutect2, varscan2
- APBA3 | c.1617C>T p.H539= | Silent (SNP) | VAF 122/251 reads (49%) | catalogued as rs1165993757; called by muse, mutect2, varscan2
- APOE | c.699C>T p.R233= | Silent (SNP) | VAF 204/425 reads (48%) | catalogued as rs1354007902; called by muse, mutect2, varscan2
- ATP10A | c.4191G>A p.A1397= | Silent (SNP) | VAF 129/303 reads (43%) | catalogued as rs139877863; called by muse, mutect2, varscan2
- ATXN2 | c.3534C>T p.A1178= (on ENST00000550104; = p.A1018= on NM_002973.4) | Silent (SNP) | VAF 172/379 reads (45%) | catalogued as rs1424424594; called by muse, mutect2, varscan2
- CARD11 | c.1719C>T p.I573= | Silent (SNP) | VAF 125/243 reads (51%) | catalogued as rs762267654, COSV62754698; called by muse, mutect2, varscan2
- CDK5RAP3 | c.618C>T p.D206= | Silent (SNP) | VAF 61/132 reads (46%) | catalogued as rs200176581; called by muse, mutect2, varscan2
- CELSR1 | c.4116C>T p.C1372= | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as rs552142268; called by muse, mutect2, varscan2
- CELSR2 | c.4950C>T p.D1650= | Silent (SNP) | VAF 158/316 reads (50%) | catalogued as rs760115202; called by muse, mutect2
- CLCNKA | c.528C>T p.I176= | Silent (SNP) | VAF 392/846 reads (46%) | called by muse, mutect2, varscan2
- COL4A4 | c.3471G>T p.G1157= | Silent (SNP) | VAF 193/409 reads (47%) | catalogued as rs759640112; called by muse, mutect2, varscan2
- CYP4F11 | c.1416G>A p.A472= | Silent (SNP) | VAF 118/237 reads (50%) | catalogued as rs1446610856, COSV56126799; called by muse, mutect2, varscan2
- DYNC1H1 | c.7275G>C p.P2425= | Silent (SNP) | VAF 228/486 reads (47%) | called by muse, mutect2, varscan2
- ETNPPL | c.37C>T p.L13= | Silent (SNP) | VAF 71/342 reads (21%) | catalogued as COSV56596647; called by muse, mutect2, varscan2
- FAT3 | c.4395C>T p.Y1465= | Silent (SNP) | VAF 153/312 reads (49%) | catalogued as rs777271764, COSV53161310, COSV99964840; called by muse, mutect2, varscan2
- FAXC | c.129C>T p.I43= | Silent (SNP) | VAF 260/576 reads (45%) | catalogued as COSV101067200; called by muse, mutect2, varscan2
- FBXO24 | c.435C>T p.H145= (on ENST00000241071 / NM_033506.3; = p.H183= on NM_012172.5) | Silent (SNP) | VAF 344/757 reads (45%) | catalogued as rs376624298; called by muse, mutect2, varscan2
- FCGBP | c.7065G>A p.P2355= | Silent (SNP) | VAF 440/1834 reads (24%) | catalogued as rs1359420715; called by muse, mutect2, varscan2
- GK3P | c.471C>A p.L157= | Silent (SNP) | VAF 273/547 reads (50%) | catalogued as rs370239408; called by muse, mutect2, varscan2
- HAPLN4 | c.939G>A p.Q313= | Silent (SNP) | VAF 191/359 reads (53%) | called by muse, mutect2, varscan2
- HTR1A | c.285G>A p.L95= | Silent (SNP) | VAF 271/614 reads (44%) | catalogued as rs200647288; called by muse, mutect2, varscan2
- LRRK2 | c.4197G>A p.E1399= | Silent (SNP) | VAF 122/221 reads (55%) | catalogued as COSV100110467; called by muse, mutect2, varscan2
- MUC3A | c.7689C>A p.I2563= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV60216083; called by mutect2, varscan2
- NAT8L | c.729G>A p.A243= | Silent (SNP) | VAF 100/205 reads (49%) | catalogued as rs770149087, COSV104404374; called by muse, mutect2, varscan2
- NLGN2 | c.1881G>A p.T627= | Silent (SNP) | VAF 199/401 reads (50%) | catalogued as rs747379386, COSV57212716; called by muse, mutect2, varscan2
- SIPA1L2 | c.4002C>T p.G1334= | Silent (SNP) | VAF 60/128 reads (47%) | catalogued as rs1223941111; called by muse, mutect2, varscan2
- SLC35B2 | c.1212C>T p.A404= | Silent (SNP) | VAF 117/275 reads (43%) | catalogued as rs778904736; called by muse, mutect2, varscan2
- SPON2 | c.564C>T p.D188= | Silent (SNP) | VAF 121/263 reads (46%) | catalogued as COSV99072948; called by muse, mutect2, varscan2
- TATDN2 | c.771C>T p.S257= | Silent (SNP) | VAF 320/629 reads (51%) | catalogued as rs954210878; called by muse, mutect2, varscan2
- TEKT5 | c.1320G>A p.L440= | Silent (SNP) | VAF 294/581 reads (51%) | called by muse, mutect2, varscan2
- TNC | c.4941C>T p.F1647= | Silent (SNP) | VAF 217/421 reads (52%) | catalogued as rs201689087, COSV60788203; called by muse, mutect2, varscan2
- TTN | c.19164A>G p.E6388= (on ENST00000591111; = p.E5461= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/138 reads (44%) | catalogued as rs767695320; called by muse, mutect2, varscan2
- ATG4D | c.236-49G>A | Intron (SNP) | VAF 52/100 reads (52%) | called by muse, mutect2, varscan2
- LRRC69 | c.184-6261C>T | Intron (SNP) | VAF 123/218 reads (56%) | catalogued as rs747399094, COSV59249348; called by muse, mutect2, varscan2
- MAP2K3 | c.50-2286C>G | Intron (SNP) | VAF 122/723 reads (17%) | called by muse, mutect2, varscan2
- MIR1270 | chr19:20397398 C>T | 3'Flank (SNP) | VAF 192/423 reads (45%) | called by muse, mutect2, varscan2
- OR10J1 | c.-25A>G | 5'UTR (SNP) | VAF 55/139 reads (40%) | called by muse, mutect2, varscan2
- RASA4CP | n.719G>A | RNA (SNP) | VAF 162/688 reads (24%) | catalogued as rs781274962; called by muse, mutect2, varscan2
- RNF170 | c.*5G>C | 3'UTR (SNP) | VAF 150/350 reads (43%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.932C>T | RNA (SNP) | VAF 50/105 reads (48%) | catalogued as rs138521906; called by muse, mutect2, varscan2
- RPL23AP42 | n.351T>G | RNA (SNP) | VAF 315/630 reads (50%) | called by muse, mutect2, varscan2
- RPP40 | c.269-475C>T | Intron (SNP) | VAF 66/181 reads (36%) | catalogued as rs544132936; called by muse, mutect2, varscan2
- SCN1A | c.4477-49_4477-48insC | Intron (INS) | VAF 81/171 reads (47%) | called by mutect2, varscan2
- TCF7L2 | c.1442+633del | Intron (DEL) | VAF 81/221 reads (37%) | called by mutect2, pindel, varscan2
- TCP1 | c.1097+129C>A | Intron (SNP) | VAF 113/264 reads (43%) | catalogued as COSV58459044; called by muse, mutect2, varscan2
- TGM6 | c.-67C>T | 5'UTR (SNP) | VAF 169/370 reads (46%) | catalogued as rs542376266; called by muse, mutect2, varscan2
- TMEM135 | c.510-18525G>T | Intron (SNP) | VAF 71/122 reads (58%) | called by muse, mutect2, varscan2
- TUBB7P | n.725T>C | RNA (SNP) | VAF 346/350 reads (99%) | called by muse, varscan2
